Gene-level copy-number profile of tumor specimen TCGA-EY-A1GC-01A from TCGA case TCGA-EY-A1GC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.0 years (22,656 days).
Specimen TCGA-EY-A1GC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.22338f69-1830-4640-a0ec-f155a46605c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A1GC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b67748cb-0ca5-42be-8c7a-1756fa0b9da6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 738; copy number 2: 12,255; copy number 3: 20,120; copy number 4: 19,460; copy number 5: 2,893; copy number 6: 1,984; copy number 7: 822; copy number 8: 331; copy number 9: 655; copy number 10: 24; copy number 12: 517; copy number 14: 5; copy number 15: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A1GC-01A-11D-A13J-01): tumor purity 0.58, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,360 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,580,013, 505 genes, copy number 12 (broad region; genes not listed).
- chr1:178,479,247–178,561,029, 6 genes, copy number 15: CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69.
- chr3:11,745–47,513,712, 751 genes, copy number 7 (broad region; genes not listed).
- chr8:38,901,235–57,423,673, 292 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr8:119,557,086–120,056,201, 12 genes, copy number 12 (within-gene range 6–12): ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr8:127,663,280–127,742,951, 3 genes, copy number 14: AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 14: MIR1204, AC084123.1.
- chr9:113,221,544–113,682,855, 15 genes, copy number 8: SLC31A1, CDC26, PRPF4, RNF183, WDR31, BSPRY, HDHD3, ALAD, POLE3, C9orf43, RGS3, AL162727.2, AL162727.3, AL162727.1, AL157702.2.
- chr10:101,131,300–101,557,321, 11 genes, copy number 7 (within-gene range 4–7): TLX1, LINC01514, SMARCE1P7, LBX1, LBX1-AS1, LINC02681, RNU2-43P, AL133387.1, AL133387.2, BTRC, RNU2-59P.
- chr14:18,333,726–32,882,830, 578 genes, copy number 9 (broad region; genes not listed).
- chr14:33,924,227–40,390,547, 122 genes, copy number 8 (broad region; genes not listed).
- chr14:58,646,631–59,184,247, 5 genes, copy number 8 (within-gene range 6–8): LINC01500, AL049873.1, AL049873.2, AKR1B1P5, PPIAP5.
- chr14:103,519,667–103,880,381, 24 genes, copy number 10: CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5, KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA, PPP1R13B, AL049840.7, AL049840.1, LINC00637, AL132712.1, AL132712.2.
- chr16:70,802,084–71,230,722, 4 genes, copy number 7 (within-gene range 2–7): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:799,310–979,776, 1 gene, copy number 7 (within-gene range 3–7): NXN.
- chr17:909,632–1,003,671, 3 genes, copy number 7: AC087392.1, AC036164.1, TIMM22.
- chr17:1,022,476–1,022,559, 1 gene, copy number 7: MIR3183.
- chr20:17,887,363–18,467,281, 25 genes, copy number 7–9 (within-gene range 3–9): AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476.

Autosomal genes at a single copy (total copy number 1): 738. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
